Somatic mutation profile of tumor specimen TARGET-30-PAPBJE-01A (aliquot TARGET-30-PAPBJE-01A-01D) from TARGET case TARGET-30-PAPBJE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.1 years (1,860 days).
Specimen TARGET-30-PAPBJE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d00b2a04-11ec-4aa8-8a5d-e5acc82c8995.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPBJE-10A (Blood Derived Normal), aliquot TARGET-30-PAPBJE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89a3af12-b587-4f2b-95fc-01e2c5b1ff40

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 22, Silent 6, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAR2 | c.392A>T p.K131M | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57923797; called by muse, mutect2, varscan2
- API5 | c.788G>A p.C263Y | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66632891; called by muse, mutect2, varscan2
- CCDC42 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs760587890, COSV53448520; called by muse, mutect2, varscan2
- CFAP54 | c.7855C>A p.Q2619K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV61571704; called by muse, mutect2, varscan2
- CNTNAP3 | c.2453G>T p.C818F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52666264; called by muse, mutect2, varscan2
- DIO3 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as rs755747625, COSV63773445; called by muse, mutect2, varscan2
- DMXL1 | c.4042C>T p.H1348Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60709139; called by muse, mutect2, varscan2
- GPSM1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs370718104; called by muse, mutect2, varscan2
- HLA-DQA1 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775152680, COSV58238358; called by muse, mutect2, varscan2
- KRI1 | c.633G>T p.E211D | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57264253; called by muse, mutect2, varscan2
- LCT | c.3238C>A p.P1080T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51544177, COSV51546767; called by muse, mutect2, varscan2
- LRP1B | c.11715C>A p.F3905L | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.137); catalogued as COSV67189331; called by muse, mutect2, varscan2
- LRRC37A3 | c.3715C>A p.Q1239K | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.678); catalogued as COSV58534932; called by muse, mutect2, varscan2
- MST1R | c.3499G>A p.G1167S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1320258189, COSV56567620, COSV99618150; called by muse, mutect2, varscan2
- NTRK3 | c.1244C>A p.P415H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV58117897; called by muse, mutect2, varscan2
- OR2T8 | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60662264; called by muse, mutect2, varscan2
- PTPN21 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60847415; called by muse, mutect2, varscan2
- SLC25A33 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV57019820; called by muse, mutect2, varscan2
- SPAG9 | c.2364C>A p.C788* (on ENST00000262013 / NM_001130528.3; = p.C774* on NM_003971.6) | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV56234131; called by muse, mutect2, varscan2
- VCAN | c.7138C>A p.Q2380K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV54102801; called by muse, mutect2, varscan2
- ZNF25 | c.252C>A p.S84R | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs765946555, COSV56922207; called by muse, mutect2, varscan2
- DCP1B | c.1774-1G>T p.X592_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | called by muse, varscan2
- MACF1 | c.18037C>T p.L6013F (on ENST00000372915; = p.L4058F on NM_012090.5) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- VPS13B | c.527C>A p.A176E | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADAM12 | c.1167C>T p.P389= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- CACNA1I | c.1050C>A p.I350= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV60805686; called by muse, mutect2, varscan2
- FLG2 | c.4701G>A p.R1567= | Silent (SNP) | VAF 123/315 reads (39%) | catalogued as COSV66167927; called by muse, mutect2, varscan2
- MACF1 | c.18036T>C p.A6012= (on ENST00000372915; = p.A4057= on NM_012090.5) | Silent (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- SLX4 | c.1098C>T p.L366= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV53563070; called by muse, mutect2, varscan2
- TM9SF4 | c.849C>A p.I283= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV54106194; called by muse, mutect2, varscan2
